MMRF case MMRF_1766 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6bcbcb87-1c05-4200-a994-9bf9a8594b6a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.8 years (22,210 days); ISS stage: I; Days to last known disease status: 1,066 days (2.9 years); Days to last follow up: 1,066 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 155 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days; Days to treatment end: 185 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 217 days; Days to treatment end: 217 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 218 days; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 339 days; Days to treatment end: 989 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,066 days (2.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 1): M Protein 1.02 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.89 mg/dL; Immunoglobulin G 19.6 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 8.6 g/dL; Glucose 6.55 mmol/L.
- Day 93 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Hemoglobin 7.63 mmol/L; Leukocytes 13.5 ×10⁹/L; Absolute Neutrophil 12.8 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 10.8 mmol/L.
- Day 184 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 4.53 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 6.55 mmol/L.
- Day 275 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.7 g/dL; Glucose 8.25 mmol/L.
- Day 367 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.6 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.9 g/dL; Glucose 6.82 mmol/L.
- Day 452: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.8 g/dL; Glucose 6.33 mmol/L.
- Day 543 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.92 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 8.14 mmol/L.
- Day 620: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.31 mg/dL; Immunoglobulin G 9.66 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 9.02 mmol/L.
- Day 714 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.17 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 2.13 g/L; Immunoglobulin M 0.46 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.8 g/dL; Glucose 8.25 mmol/L.
- Day 795: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.94 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 9.19 mmol/L.
- Day 918 (ECOG 1): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 10.6 mmol/L.
- Day 989: M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 0.99 g/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 13.6 mmol/L.
- Day 1,066 (ECOG 1): M Protein 0.99 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 22.1 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 65 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 7.9 g/dL; Glucose 12.9 mmol/L.

Other clinical attributes
- Day -3: Weight: 103 kg; Height: 181 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1766_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1766_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
